Gene-level copy-number profile of tumor specimen TCGA-IN-8663-01A from TCGA case TCGA-IN-8663, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.9 years (25,172 days).
Specimen TCGA-IN-8663-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.87ba8a88-c3ba-4dd5-a2ab-47ac920e6441.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-8663-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1c49ae6-165e-4daa-bbcc-dd992dd23372

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 2,325; copy number 2: 14,377; copy number 3: 23,757; copy number 4: 15,443; copy number 5: 2,222; copy number 6: 351; copy number 7: 242; copy number 8: 769; copy number 9: 184; copy number 11: 16; copy number 13: 23; copy number 14: 22; copy number 16: 11; copy number 19: 19; copy number 31: 11; copy number 48: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-8663-01A-11D-2390-01): tumor purity 0.75, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:145,481,194–145,559,176, 1 gene (within-gene range 0–2): SMAD1.
- chr7:111,091,006–111,125,454, 1 gene: LRRN3.
- chr17:68,246,629–69,060,949, 15 genes: AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9.
- chr18:65,750,252–65,890,337, 2 genes (within-gene range 0–2): CDH7, AC023394.2.
- chr21:14,027,419–14,144,468, 1 gene (within-gene range 0–1): AP001347.1.
- chr21:14,108,813–14,775,262, 10 genes: LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16.
- chr21:14,829,154–14,829,989, 1 gene: RBMX2P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,313 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,269,754–8,516,759, 8 genes, copy number 9 (within-gene range 5–9): HTRA3, LINC02517, AC104825.1, ACOX3, RNA5SP152, TRMT44, AC105345.2, AC105345.1.
- chr7:89,754,620–97,201,483, 125 genes, copy number 9–13 (broad region; genes not listed).
- chr8:62,110,524–95,811,254, 513 genes, copy number 8 (broad region; genes not listed).
- chr8:97,868,840–115,809,673, 247 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr9:120,902,393–121,050,275, 2 genes, copy number 9 (within-gene range 4–9): TRAF1, C5.
- chr12:22,046,218–25,959,765, 58 genes, copy number 14–48: CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1.
- chr13:69,700,594–84,069,408, 149 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr13:106,753,247–112,887,168, 88 genes, copy number 7–16 (broad region; genes not listed).
- chr15:62,362,029–62,844,631, 4 genes, copy number 7 (within-gene range 4–7): HMGN1P26, AC032011.1, TLN2, MGC15885.
- chr17:26,981,694–28,614,185, 83 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:32,083,179–32,491,253, 29 genes, copy number 7 (within-gene range 4–7): AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,531,492, 7 genes, copy number 7: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.

Autosomal genes at a single copy (total copy number 1): 1,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
